CCDI case PBBRNA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/c714df3a-5225-438c-90da-35eaa54c89a1

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Infantile fibrosarcoma: ICD-O-3 morphology code: 8814/3; Tissue or organ of origin: Jejunum; Age at diagnosis: 0.0 years (1 days).

Biospecimens (3 samples)
- Sample 0DGMHB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGMHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DGMI4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
